Somatic mutation profile of tumor specimen TCGA-50-5044-01A (aliquot TCGA-50-5044-01A-21D-1855-08) from TCGA case TCGA-50-5044, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.7 years (26,567 days).
Specimen TCGA-50-5044-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7179d2e-e846-4247-a963-c960ea4511c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5044-10A (Blood Derived Normal), aliquot TCGA-50-5044-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1b30b2d-d92e-4d52-90f1-846bf9f5dba9

The open-access MAF lists 131 somatic variants for this specimen: 88 protein-altering or splice-affecting, 38 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 38, Nonsense Mutation 5, 5'UTR 2, RNA 1, 3'Flank 1, Intron 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>C p.D634H (on ENST00000288602 / NM_001374244.1; = p.D594H on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABLIM2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56404755; called by muse, mutect2, varscan2
- ABLIM3 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV58643575; called by muse, mutect2
- ACTR6 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51841861; called by muse, mutect2
- ADCY5 | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59196455, COSV59198207; called by muse, mutect2, varscan2
- ADGRV1 | c.9805G>C p.G3269R | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV67985558; called by muse, mutect2
- ADNP | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1231041828, COSV62425361; called by muse, mutect2, varscan2
- AKAP6 | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 27/193 reads (14%) | catalogued as COSV55214316; called by muse, mutect2, varscan2
- ALOX15B | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV66479477; called by muse, mutect2, varscan2
- ATMIN | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55146181; called by muse, mutect2, varscan2
- BLM | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV61924184; called by muse, mutect2, varscan2
- BPIFB2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.172); catalogued as COSV50064915; called by muse, mutect2
- CC2D2A | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1418947124, COSV67503729; called by muse, mutect2
- CCDC18 | c.3487G>A p.E1163K (on ENST00000343253 / NM_001306076.1; = p.E1164K on NM_206886.4) | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as rs1366138742, COSV58143685; called by muse, mutect2
- CDH19 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV50957281, COSV50978449; called by muse, mutect2, varscan2
- CENPF | c.4408G>C p.E1470Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV65275112, COSV65277252; called by muse, mutect2, varscan2
- CEP350 | c.7681C>G p.Q2561E | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.92); catalogued as rs763620220, COSV62602831; called by muse, mutect2, varscan2
- CYP27A1 | c.825G>T p.W275C | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51468296; called by muse, mutect2, varscan2
- DCAF6 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV56579010; called by muse, mutect2, varscan2
- DCLRE1A | c.902C>G p.S301C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63748774; called by muse, mutect2, varscan2
- DDX27 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65629758; called by muse, mutect2, varscan2
- EGFL6 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63633941, COSV63634128; called by muse, mutect2
- EIF3B | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV62803468; called by muse, mutect2
- EPHB4 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62268902; called by muse, mutect2, varscan2
- F5 | c.6280G>C p.D2094H | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs768862607, COSV63124199; called by muse, mutect2, varscan2
- FAM155A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV65562644; called by muse, mutect2, varscan2
- FANCI | c.2145G>C p.K715N | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55527374; called by muse, mutect2
- FGB | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57418426; called by muse, mutect2
- FRAS1 | c.6713G>C p.R2238T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53612045; called by muse, mutect2
- G3BP1 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62366189; called by muse, mutect2
- GLB1L2 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV60278693; called by muse, mutect2, varscan2
- GRP | c.438C>G p.N146K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV56879571; called by muse, mutect2
- GSS | c.1098G>C p.Q366H | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013742273, COSV53624879; called by muse, mutect2
- HECTD1 | c.6709G>A p.E2237K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.973); catalogued as rs770309354, COSV67946399; called by mutect2, varscan2
- HIP1 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV100417795, COSV61186066; called by muse, mutect2
- HOXC6 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.501); catalogued as COSV54536949, COSV54537327; called by muse, mutect2, varscan2
- IL16 | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.055); catalogued as COSV57263773; called by muse, mutect2, varscan2
- IRF2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101165867, COSV66928529, COSV66929484; called by muse, mutect2
- ITCH | c.2038A>G p.I680V (on ENST00000262650 / NM_001257137.3; = p.I639V on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs139633287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGAX | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV51645946; called by muse, mutect2
- ITPRID1 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV60075167; called by muse, mutect2, varscan2
- KCTD16 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs760934349, COSV72578873; called by muse, mutect2, varscan2
- KLK2 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV57569601; called by muse, mutect2, varscan2
- KRT28 | c.887C>G p.S296* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV60685181, COSV60687082; called by muse, mutect2, varscan2
- LATS2 | c.3248G>A p.C1083Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV66875798; called by muse, mutect2, varscan2
- MARCHF8 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60572433, COSV60573492; called by muse, mutect2, varscan2
- MAT2B | c.532G>C p.A178P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV55200896; called by muse, mutect2, varscan2
- MCOLN1 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV51175672; called by muse, mutect2
- METTL14 | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV66310620; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV56620019; called by muse, mutect2
- MROH2B | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV68184397, COSV68189066; called by muse, mutect2
- MTCL1 | c.3426C>G p.F1142L (on ENST00000306329 / NM_001378206.1; = p.F823L on NM_015210.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60406255; called by mutect2, varscan2
- MUC16 | c.12554C>T p.S4185F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); catalogued as rs770450829, COSV67467369; called by muse, mutect2
- MYH6 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV62450700; called by muse, mutect2
- NAA35 | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64484728; called by muse, mutect2
- NALCN | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51936912; called by muse, mutect2
- P3H4 | c.781A>T p.I261L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV58636721; called by muse, mutect2, varscan2
- PRDX2 | c.77A>T p.K26I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100040059; called by muse, mutect2, varscan2
- PSD3 | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV54071865; called by muse, mutect2
- PTBP2 | c.1493G>C p.R498T (on ENST00000426398 / NM_001300986.2; = p.X489_splice on NM_021190.4) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV64624527; called by muse, mutect2, varscan2
- PYCR2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV59524968; called by muse, mutect2, varscan2
- RAD51C | c.485del p.G162Efs*9 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | catalogued as COSV53623991; called by mutect2, pindel, varscan2
- RNF169 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55132572; called by muse, mutect2
- RNF19B | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.225); catalogued as rs371235809, COSV52390122; called by muse, mutect2, varscan2
- RNF31 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as COSV53759615, COSV53760434; called by muse, mutect2
- RTEL1 | c.2803C>T p.L935F | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs769930889, COSV58894274; called by muse, mutect2
- SLC5A11 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV61741026, COSV61741703; called by muse, mutect2, varscan2
- SLC7A7 | c.1507C>G p.P503A | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53537172; called by muse, mutect2, varscan2
- SLC8A1 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as COSV60480934, COSV60481121; called by muse, mutect2
- SMYD1 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV70225196; called by muse, mutect2
- SYNE1 | c.20065G>C p.E6689Q (on ENST00000367255 / NM_182961.4; = p.E6618Q on NM_033071.3) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV54986722; called by muse, mutect2, varscan2
- SYNE2 | c.16300G>C p.E5434Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV59951608; called by muse, mutect2, varscan2
- SZT2 | c.3778C>T p.Q1260* (on ENST00000634258 / NM_001365999.1; = p.Q1203* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65170039; called by muse, mutect2, varscan2
- TARS3 | c.1967G>A p.S656N | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV60108153; called by muse, mutect2, varscan2
- TBC1D31 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV54866489; called by muse, mutect2, varscan2
- TM2D1 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.215); catalogued as COSV99623261; called by muse, mutect2
- TMEM190 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52581806; called by muse, mutect2, varscan2
- TMTC3 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57124025; called by muse, mutect2, varscan2
- UBA6 | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV59177389; called by muse, mutect2, varscan2
- UBR4 | c.3386C>G p.S1129* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV64390133; called by muse, mutect2
- VPS13B | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV62019696; called by muse, varscan2
- VPS13D | c.7288C>T p.R2430C | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs540082212, COSV50640380; called by muse, mutect2, varscan2
- WDR81 | c.5812C>T p.R1938C (on ENST00000409644 / NM_001163809.2; = p.R887C on NM_152348.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756853082, COSV100488946, COSV58483051; called by muse, mutect2
- YOD1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1013716970, COSV100262809; called by muse, mutect2, varscan2
- ZNF253 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV63037238; called by muse, mutect2
- ZNF391 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV55123187; called by muse, mutect2
- ZNF655 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs141925358; called by mutect2, varscan2
- AFF2 | c.699C>T p.I233= | Silent (SNP) | VAF 36/281 reads (13%) | catalogued as COSV60660738, COSV60665610; called by muse, mutect2, varscan2
- AKAP12 | c.636T>G p.A212= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV53575408; called by muse, mutect2
- AMZ2 | c.654G>A p.V218= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV63083051; called by muse, mutect2, varscan2
- APAF1 | c.771G>A p.Q257= (on ENST00000551964 / NM_181861.2; = p.Q246= on NM_001160.3) | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV59664258; called by muse, mutect2, varscan2
- CD74 | c.660C>T p.I220= | Silent (SNP) | VAF 14/191 reads (7%) | catalogued as COSV50532682; called by muse, mutect2
- CFAP46 | c.6906G>A p.S2302= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as rs767875552, COSV54152755; called by muse, mutect2, varscan2
- CLIC1 | c.288G>A p.L96= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV101007419; called by muse, mutect2, varscan2
- DCAF5 | c.2442G>A p.R814= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV58460412; called by muse, mutect2
- DDC | c.1350C>T p.I450= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV63565289; called by muse, mutect2, varscan2
- ECI1 | c.286C>T p.L96= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV57043703; called by muse, mutect2, varscan2
- EPHA10 | c.546G>A p.P182= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV60403236; called by muse, mutect2, varscan2
- FABP6 | c.57G>A p.L19= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV101221146; called by muse, mutect2, varscan2
- FBXO38 | c.3048G>A p.Q1016= (on ENST00000340253 / NM_205836.3; = p.Q941= on NM_030793.5) | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV57028019; called by muse, mutect2
- GADD45G | c.228C>T p.I76= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99378516; called by muse, mutect2, varscan2
- H2AC20 | c.282G>A p.L94= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV58612033, COSV58613007; called by muse, mutect2, varscan2
- HES4 | c.171C>G p.L57= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs754074223, COSV100515105; called by muse, mutect2, varscan2
- IGKV1-6 | c.291C>A p.I97= | Silent (SNP) | VAF 36/315 reads (11%) | called by muse, mutect2, varscan2
- KRT13 | c.1110C>T p.I370= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs147022064, COSV55840058; called by muse, mutect2, varscan2
- LGALS2 | c.351G>A p.L117= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as COSV50756515; called by muse, mutect2, varscan2
- MRC1 | c.2955C>G p.V985= | Silent (SNP) | VAF 26/221 reads (12%) | called by muse, mutect2, varscan2
- MTIF2 | c.2082C>T p.L694= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1473411743, COSV55051634; called by muse, mutect2
- MTUS2 | c.3861C>G p.L1287= (on ENST00000612955 / NM_001366650.1; = p.L266= on NM_015233.6) | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV66421320; called by muse, mutect2, varscan2
- NRSN1 | c.36G>A p.Q12= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1030746252, COSV65893931, COSV65893961; called by muse, mutect2, varscan2
- NUP188 | c.3540C>A p.I1180= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV65362309; called by muse, mutect2, varscan2
- PKNOX1 | c.894G>A p.Q298= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV52336443; called by muse, mutect2, varscan2
- PNPLA8 | c.2001G>C p.V667= | Silent (SNP) | VAF 13/147 reads (9%) | catalogued as COSV57552519; called by muse, mutect2
- PROM1 | c.984C>T p.S328= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV71699461; called by muse, varscan2
- RANBP9 | c.1074C>T p.I358= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as rs186966416, COSV50580651; called by muse, mutect2
- SUPT6H | c.3204G>A p.K1068= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV58927513; called by muse, mutect2
- TAS2R7 | c.558C>T p.L186= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99553516; called by muse, mutect2, varscan2
- TASOR | c.3216C>G p.L1072= (on ENST00000355628 / NM_001365636.2; = p.L696= on NM_015224.3) | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs1338896967, COSV100843261, COSV62930235; called by muse, mutect2
- TFAP4 | c.348C>T p.F116= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV52597662; called by muse, mutect2, varscan2
- TFAP4 | c.222C>A p.L74= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV52597673; called by muse, varscan2
- TIMELESS | c.570C>T p.L190= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV57511600; called by muse, mutect2, varscan2
- TM9SF2 | c.96G>A p.R32= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV63480872; called by mutect2, varscan2
- TUBGCP5 | c.333G>C p.L111= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- UMOD | c.1710C>G p.L570= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56775905; called by muse, mutect2, varscan2
- UTP20 | c.6285G>A p.L2095= | Silent (SNP) | VAF 16/190 reads (8%) | catalogued as rs1367784524, COSV55377536; called by muse, mutect2
- ACSL5 | c.-122G>T | 5'UTR (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100634425; called by muse, mutect2, varscan2
- ACSL5 | c.-121G>T | 5'UTR (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100634426; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37169046 C>G | 3'Flank (SNP) | VAF 23/187 reads (12%) | catalogued as COSV57060596; called by muse, mutect2, varscan2
- OR2W5 | n.979C>T | RNA (SNP) | VAF 21/115 reads (18%) | catalogued as rs201670897; called by muse, mutect2, varscan2
- TMEM8B | c.819+115C>G | Intron (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100941512; called by muse, mutect2, varscan2
